Gene-level copy-number profile of tumor specimen HCM-SANG-0300-C15-01A-01D-A80T-32 from HCMI case HCM-SANG-0300-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0300-C15-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f58ada30-6179-4899-aadb-5bb135541ff3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0300-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/031d4f73-7adc-467a-8ffa-a17206e7ac28

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 535; copy number 1: 2; copy number 2: 18,827; copy number 3: 252; copy number 4: 36,051; copy number 5: 86; copy number 6: 2,731; copy number 7: 105; copy number 8: 130; copy number 9: 4; copy number 10: 171; copy number 11: 7; copy number 14: 8.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–91,112,790, 2 genes (within-gene range 0–2): TMSB4XP8, AC004054.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr16:68,686,399–68,835,541, 3 genes (within-gene range 0–2): HSPE1P5, CDH1, RNA5SP429.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 190 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,871,188–111,716,691, 37 genes, copy number 10 (within-gene range 4–10): CD53, AL360270.2, AL360270.1, LRIF1, AL360270.3, CCNT2P1, RNA5SP54, DRAM2, CEPT1, AL355816.1, AL355816.2, DENND2D, CHI3L2, CHIAP1, CHIAP2, CHIA, AL356387.1, AL356387.2, PIFO, CHIAP3, HIGD1AP12, PGBP, OVGP1, AL390195.2, UBE2FP3, AL390195.1, WDR77, Y_RNA, ATP5PB, C1orf162, TMIGD3, RNU6-792P, ADORA3, RAP1A, LINC01160, KRT18P57, RNU6-151P.
- chr3:63,228,315–66,623,102, 42 genes, copy number 10 (within-gene range 2–10): SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040, MAGI1, AC121493.1, ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1, SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1.
- chr3:67,654,669–75,371,342, 91 genes, copy number 10 (broad region; genes not listed).
- chr10:62,339,553–63,155,031, 12 genes, copy number 10–14: AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2.
- chr10:63,664,664–65,017,639, 8 genes, copy number 9–11: AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
